Somatic mutation profile of tumor specimen TCGA-29-2431-01A (aliquot TCGA-29-2431-01A-01D-1526-09) from TCGA case TCGA-29-2431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 59.8 years (21,833 days).
Specimen TCGA-29-2431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bec69899-34d4-4bc5-95b6-c8defc1a69e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2431-10A (Blood Derived Normal), aliquot TCGA-29-2431-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaad58b2-b748-4967-a8db-3148b82d23e2

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Frame Shift Del 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 44/65 reads (68%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ANK2 | c.1930A>T p.I644L | Missense Mutation (SNP) | VAF 172/268 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV52159372; called by muse, mutect2, varscan2
- ASPRV1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 127/173 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs149847323; called by muse, mutect2, varscan2
- CERKL | c.1421G>C p.R474T (on ENST00000339098 / NM_001030311.2; = p.R448T on NM_201548.5) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59207144, COSV59209014; called by muse, mutect2, varscan2
- EPRS1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100859537; called by muse, mutect2
- GLE1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 212/821 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs368484174; called by muse, mutect2, varscan2
- GOLGA3 | c.3608G>A p.G1203E | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs199942065, COSV52647414; called by muse, mutect2
- HPS6 | c.1291A>G p.T431A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54625557; called by muse, mutect2, varscan2
- IFI16 | c.1843G>A p.V615I (on ENST00000295809 / NM_001364867.2; = p.V559I on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs994934220, COSV55533532; called by muse, mutect2, varscan2
- IFI27L1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as rs545021441, COSV67628622; called by muse, mutect2, varscan2
- IFT122 | c.3604G>A p.A1202T (on ENST00000348417 / NM_052989.3; = p.A1143T on NM_018262.4) | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56202698, COSV99959405; called by muse, mutect2, varscan2
- IFT57 | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52709455; called by muse, mutect2, varscan2
- IGSF10 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs374899455; called by muse, mutect2, varscan2
- KCNB1 | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100870607; called by muse, mutect2
- NYAP1 | c.45C>A p.H15Q | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); catalogued as COSV55718647; called by muse, mutect2, varscan2
- OR12D3 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65827755; called by muse, mutect2, varscan2
- OR4P4 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV58921797; called by muse, mutect2, varscan2
- RHCG | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 133/503 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV51515799; called by muse, mutect2, varscan2
- RHEX | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV58980344; called by muse, mutect2, varscan2
- SLC27A5 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54019361; called by muse, mutect2, varscan2
- SLC28A1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV54477034, COSV54478725; called by muse, mutect2, varscan2
- SLFNL1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs368949883; called by muse, mutect2, varscan2
- SNTB1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV67325991; called by muse, mutect2, varscan2
- SP100 | c.1884G>C p.K628N | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV50979134; called by muse, mutect2, varscan2
- SPTAN1 | c.7227T>G p.I2409M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV100824100; called by muse, mutect2
- STPG2 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99762011; called by muse, mutect2
- TLR4 | c.963A>T p.E321D (on ENST00000355622 / NM_138554.5; = p.E281D on NM_003266.4) | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62923177, COSV62923626; called by muse, mutect2, varscan2
- TNFRSF11A | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.053); catalogued as rs745445366, COSV54023244; called by muse, mutect2, varscan2
- VASP | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs777492777, COSV55606619; called by muse, mutect2, varscan2
- WASHC5 | c.2387A>G p.D796G | Missense Mutation (SNP) | VAF 161/862 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV59196102; called by muse, mutect2, varscan2
- IFNL3 | c.440_458del p.T147Ifs*34 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | called by mutect2, varscan2
- PTPRG | c.2931del p.I977Mfs*4 | Frame Shift Del (DEL) | VAF 76/219 reads (35%) | called by mutect2, pindel, varscan2
- ACTC1 | c.246C>T p.D82= | Silent (SNP) | VAF 106/393 reads (27%) | catalogued as rs373261583; ClinVar: likely benign; called by muse, mutect2, varscan2
- AFF4 | c.3075A>C p.S1025= | Silent (SNP) | VAF 83/280 reads (30%) | catalogued as COSV54794410; called by muse, mutect2, varscan2
- COP1 | c.2100T>C p.V700= | Silent (SNP) | VAF 52/373 reads (14%) | catalogued as COSV58166619; called by muse, mutect2, varscan2
- SPAG16 | c.1233T>C p.T411= | Silent (SNP) | VAF 75/221 reads (34%) | catalogued as COSV59090696; called by muse, mutect2, varscan2
- TNNI3K | c.2220C>T p.L740= | Silent (SNP) | VAF 120/394 reads (30%) | catalogued as COSV53948133; called by muse, mutect2, varscan2
- UBE2Q2 | c.846T>C p.P282= | Silent (SNP) | VAF 76/289 reads (26%) | catalogued as COSV51192882; called by muse, mutect2, varscan2
- CCDC60 | c.*2C>G | 3'UTR (SNP) | VAF 19/344 reads (6%) | catalogued as rs1296117322, COSV100555842; called by muse, mutect2
